Gene-level copy-number profile of tumor specimen TCGA-85-8350-01A from TCGA case TCGA-85-8350, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.7 years (22,526 days).
Specimen TCGA-85-8350-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.61bddb00-46f8-448b-9767-65d032b3fa3d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8350-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b97eba8d-4acf-4d1d-ac31-5a92699ae2a6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 8; copy number 2: 782; copy number 3: 10,879; copy number 4: 17,194; copy number 5: 13,069; copy number 6: 8,783; copy number 7: 2,424; copy number 8: 1,345; copy number 9: 3,789; copy number 10: 232; copy number 14: 30; copy number 17: 445; copy number 18: 114; copy number 20: 81; copy number 21: 375; copy number 32: 94; copy number 35: 174.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8350-01A-11D-2292-01): tumor purity 0.32, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:120,762,510–120,904,358, 2 genes (within-gene range 0–4): SPPL3, ARF1P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,334 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–69,942,945, 1,152 genes, copy number 9 (broad region; genes not listed).
- chr3:90,030,284–90,184,733, 2 genes, copy number 10: U3, RNU6-712P.
- chr3:100,492,619–117,544,311, 228 genes, copy number 9 (broad region; genes not listed).
- chr3:163,026,396–194,145,971, 492 genes, copy number 18–35 (broad region; genes not listed).
- chr3:196,197,452–198,222,513, 81 genes, copy number 20 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 17–21 (broad region; genes not listed).
- chr12:66,767–110,218,793, 2,409 genes, copy number 9 (broad region; genes not listed).
- chr17:19,061,912–21,193,265, 131 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr19:18,306,236–20,809,995, 129 genes, copy number 10–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
